Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AAB6, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AAB6-01A (Primary Tumor).

[page 1 of 3]
Surgery date: Surgical Pathology
REVISED REPORT (Addendum/Procedure included)

ICD-O-3
Adeno carcinoma duct NOS
8500/3
Site: Pancreas body C25.1
JA 5/5/14

DIAGNOSIS:

- A. Lymph nodes, common hepatic artery, biopsy: Multiple (2) lymph nodes are negative for tumor.
- B. Soft tissue, celiac axis stump, biopsy: Fragment of nerve trunk and adjacent soft tissue. No evidence of malignancy.
- C. Celiac artery, margin, biopsy: Fragment of arterial wall. Negative for tumor.
- D. Pancreatic neck, margin, biopsy: Negative for tumor.
- E. Pancreatic body/tail, spleen, and celiac axis, partial pancreatectomy and splenectomy: Invasive moderately differentiated ductal adenocarcinoma is identified forming a solid mass (5.0 cm) located in the pancreatic body. The tumor extends beyond pancreas involves peripancreatic soft tissue. Angiolymphatic invasion is absent. Perineural invasion is absent. Tumor necrosis is absent. All surgical resection margins are negative for tumor (minimum tumor free margin, 2.5 cm, pancreatic neck margin). The adjacent non-neoplastic pancreatic parenchyma contains PanIN (1B). Multiple (16) regional lymph nodes are negative for metastatic tumor.

With available surgical material [AJCC pT3 N0] (7th edition, 2010).

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

Interpreted by:
Report electronically signed by
Transcribed by:

ADDENDUM:

Spleen is unremarkable and negative for tumor.

Transcribed by:

Signed by

[page 2 of 3]
GROSS DESCRIPTION:

A. Received fresh labeled "common hepatic artery lymph nodes" is a 1.3 x 1.3 x 0.5 cm portion of tan-red fibroadipose tissue. A 0.8 x 0.4 x 0.3 cm lymph node is present. All submitted. Grossed by

B. Received fresh labeled "celiac axis stump tissue" is a 0.8 x 0.3 x 0.3 cm fragment of red-tan soft tissue. All submitted. Grossed by

C. Received fresh labeled "celiac artery margin, margin up" is a 1.0 x 0.5 x 0.3 cm fragment of tan, ring-shaped soft tissue. All submitted. Grossed by

D. Received fresh labeled "pancreatic neck margin, margin up" is a 2.5 x 1.5 x 0.4 cm portion of bloody pancreatic tissue. All submitted. Grossed by

E. Received fresh labeled "distal pancreas, spleen, and celiac axis" is a distal pancreatectomy specimen consisting of 17.0 x 9.0 x 4.0 cm portion of pancreas and a 295 gram, 13.0 x 9.0 x 4.0 cm spleen. A 5.0 x 3.5 x 3.0 cm mass is present within the pancreas 2.5 cm from the proximal pancreatic margin. The mass does not appear to be confined to the pancreas, grossly, and appears to extend into peripancreatic soft tissue. Peripancreatic lymph nodes and splenic hilar lymph nodes are identified. The spleen is grossly unremarkable. Representative sections submitted. Grossed by

BLOCK SUMMARY:

Part A: Common hepatic artery lymph nodes

- 1 Common hepatic artery
- 2 Common hepatic arteryLN1(A1)

Part B: Celiac axis stump tissue

- 1 Celiac axis stump tissue

Part C: Celiac artery margin

- 1 Celiac artery margin

Part D: Pancreatic neck margin

- 1 Pancreatic neck margin

Part E: Distal pancreas, spleen and celiac axis

- 1 Pancreas tumor
- 2 Tumor/soft tissue
- 3 Peripancreatic Ln 2(E1)
- 4 Peripancreatic Ln 2(E2)

[page 3 of 3]
- 5 Peripancreatic Ln 1(E3)
- 6 Peripancreatic LN 4(E4)
- 7 Peripancreatic Ln 3 (E5)
- 8 Peripancreatic Ln 1 (E6)
- 9 Peripancreatic Ln 2(E7)
- 10 Spleen

Source: NCI Genomic Data Commons file 6355fa3f-3751-40fa-9dc2-513c03fb916a (TCGA-2J-AAB6.1FE3683C-294A-4FC5-A3F7-7DE1EFEFF11A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).